CCDI case PBBIVB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d7c2ba7a-8db6-4996-9df2-7e320abc6d6e

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.9 years (5,064 days).

Biospecimens (3 samples)
- Sample 0D9MK9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D9MKF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0D9MKG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
